Somatic mutation profile of tumor specimen 0DSHT4 from CCDI case PBCHJB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 15.7 years (5,718 days).
Specimen 0DSHT4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6044a3bd-7028-4f62-add9-7db3b65f38f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSHTE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60c9c193-570b-41af-9f89-f0a5b3f71839

The open-access MAF lists 72 somatic variants for this specimen: 43 protein-altering or splice-affecting, 15 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, 3'UTR 5, Intron 5, 5'UTR 3, Nonsense Mutation 2, Splice Region 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP12A | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.598); catalogued as rs766134278; called by mutect2, varscan2
- AQP12B | c.535G>A p.A179T (on ENST00000621682; = p.A191T on NM_001102467.2) | Missense Mutation (SNP) | VAF 71/433 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.598); catalogued as rs1236702720; called by muse, varscan2
- DNAJC6 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 93/330 reads (28%) | catalogued as COSV54774460; called by muse, mutect2, varscan2
- EFL1 | c.2057C>T p.S686F | Missense Mutation (SNP) | VAF 117/267 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs201252731; called by muse, mutect2, varscan2
- EVPL | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 178/493 reads (36%) | catalogued as rs1260296569, COSV56910809; called by muse, mutect2, varscan2
- FNDC3B | c.2250G>C p.G750= | Splice Region (SNP) | VAF 87/187 reads (47%) | catalogued as rs780955280; called by muse, mutect2, varscan2
- MUC16 | c.37289A>G p.N12430S | Missense Mutation (SNP) | VAF 116/351 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.315); catalogued as rs767699934; called by muse, mutect2, varscan2
- MUC16 | c.35953C>A p.P11985T | Missense Mutation (SNP) | VAF 109/327 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as rs372214978; called by muse, mutect2, varscan2
- MYLK3 | c.2171T>C p.I724T | Missense Mutation (SNP) | VAF 189/588 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200515683; called by muse, varscan2
- MYORG | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1033781264, COSV52628447; called by muse, mutect2, varscan2
- NWD2 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 92/225 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs535613170, COSV58753503; called by muse, mutect2, varscan2
- OR14K1 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 187/568 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as rs777219776; called by muse, mutect2, varscan2
- OR2T6 | c.117G>T p.M39I | Missense Mutation (SNP) | VAF 159/511 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV63216283; called by muse, mutect2
- PAPPA | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs190714711, COSV60290334; called by muse, mutect2, varscan2
- RIN3 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as rs781172457; called by muse, mutect2, varscan2
- ABCB1 | c.1064T>C p.F355S | Missense Mutation (SNP) | VAF 184/569 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ACTRT2 | c.97C>A p.H33N | Missense Mutation (SNP) | VAF 108/417 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ATP10A | c.2689G>T p.V897F | Missense Mutation (SNP) | VAF 160/488 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by mutect2, varscan2
- CACNA1C | c.1633C>G p.H545D | Missense Mutation (SNP) | VAF 174/711 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CCDC34 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP3B | c.1771T>C p.S591P | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CUX2 | c.1842G>C p.Q614H | Missense Mutation (SNP) | VAF 148/668 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- CYP4F2 | c.1068G>T p.Q356H | Missense Mutation (SNP) | VAF 135/470 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- DST | c.12007G>A p.G4003S (on ENST00000361203 / NM_001374722.1; = p.G1591S on NM_015548.5) | Missense Mutation (SNP) | VAF 138/531 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- DUOX1 | c.2477T>A p.L826Q | Missense Mutation (SNP) | VAF 218/481 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EIF2S1 | c.244T>C p.Y82H | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM171A2 | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXI1 | c.600C>A p.D200E | Missense Mutation (SNP) | VAF 90/390 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- GLUL | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 109/413 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- HCAR1 | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 466/8270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ILDR1 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 174/404 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IRS1 | c.20G>C p.S7T | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF15 | c.2797A>C p.K933Q | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRT1 | c.1451C>A p.T484N | Missense Mutation (SNP) | VAF 84/404 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PARD3B | c.2612G>C p.G871A (on ENST00000406610 / NM_001302769.2; = p.G802A on NM_057177.7) | Missense Mutation (SNP) | VAF 92/292 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- PRSS22 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- REV3L | c.4741A>G p.R1581G | Missense Mutation (SNP) | VAF 196/632 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SBNO2 | c.1805G>A p.G602D | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SCRIB | c.4440_4447del p.P1481Cfs*88 | Frame Shift Del (DEL) | VAF 92/837 reads (11%) | called by mutect2, pindel, varscan2
- SLC38A1 | c.1456G>C p.G486R | Missense Mutation (SNP) | VAF 92/438 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- TINAGL1 | c.1069C>A p.L357M | Missense Mutation (SNP) | VAF 134/424 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TSHZ2 | c.1180C>A p.Q394K | Missense Mutation (SNP) | VAF 261/429 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UBE2O | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 91/356 reads (26%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AHDC1 | c.3561C>T p.S1187= | Silent (SNP) | VAF 85/358 reads (24%) | catalogued as rs1428034711, COSV55938090; called by muse, mutect2, varscan2
- APC | c.1242C>A p.R414= | Silent (SNP) | VAF 189/681 reads (28%) | catalogued as CD058116, CS106546, COSV57335111; called by muse, mutect2, varscan2
- ARAP2 | c.2643C>G p.S881= | Silent (SNP) | VAF 88/194 reads (45%) | called by muse, mutect2, varscan2
- BTBD7 | c.2448C>T p.Y816= | Silent (SNP) | VAF 16/209 reads (8%) | called by muse, mutect2
- CRNN | c.711T>G p.G237= | Silent (SNP) | VAF 45/715 reads (6%) | called by muse, mutect2
- GLIPR1 | c.186A>G p.P62= | Silent (SNP) | VAF 159/583 reads (27%) | called by muse, mutect2, varscan2
- MGAT5 | c.168G>A p.R56= | Silent (SNP) | VAF 42/510 reads (8%) | called by muse, mutect2
- ORMDL1 | c.45T>A p.R15= | Silent (SNP) | VAF 132/512 reads (26%) | called by muse, mutect2, varscan2
- PBX1 | c.1158T>C p.D386= | Silent (SNP) | VAF 138/480 reads (29%) | called by muse, mutect2, varscan2
- PCDHB5 | c.924C>T p.F308= | Silent (SNP) | VAF 198/661 reads (30%) | called by muse, mutect2, varscan2
- PLCG1 | c.3621C>A p.I1207= | Silent (SNP) | VAF 221/413 reads (54%) | catalogued as COSV99054931; called by muse, mutect2, varscan2
- SELENOI | c.147G>A p.A49= | Silent (SNP) | VAF 77/281 reads (27%) | catalogued as rs372437710, COSV99564304; called by muse, mutect2, varscan2
- SVEP1 | c.9138T>C p.C3046= | Silent (SNP) | VAF 13/309 reads (4%) | called by muse, mutect2
- TNS1 | c.2817G>A p.G939= | Silent (SNP) | VAF 114/416 reads (27%) | called by muse, mutect2, varscan2
- ZNF804B | c.2286C>T p.C762= | Silent (SNP) | VAF 172/501 reads (34%) | catalogued as rs923729131; called by muse, mutect2, varscan2
- AC048338.2 | c.*403C>T | 3'UTR (SNP) | VAF 170/5994 reads (3%) | catalogued as rs772290509, COSV57335909; called by muse, mutect2
- AC084816.1 | n.1088A>G | RNA (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- FOLH1 | c.119-649T>C | Intron (SNP) | VAF 77/185 reads (42%) | called by muse, mutect2, varscan2
- GIMD1 | c.*79G>A | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2
- GOLGA4 | c.6192+15_6192+18del | Intron (DEL) | VAF 92/196 reads (47%) | catalogued as rs1559443678; called by mutect2, pindel, varscan2
- GULP1 | c.*69T>C | 3'UTR (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2, varscan2
- JRK | c.*45C>T | 3'UTR (SNP) | VAF 48/251 reads (19%) | catalogued as rs1378786812; called by muse, mutect2, varscan2
- KIF21A | c.-36C>T | 5'UTR (SNP) | VAF 89/393 reads (23%) | catalogued as rs1041864935; called by muse, mutect2, varscan2
- MDM1 | c.-15C>G | 5'UTR (SNP) | VAF 144/4264 reads (3%) | catalogued as rs575599732; called by muse, mutect2
- SLC25A17 | c.115+1706G>T | Intron (SNP) | VAF 144/549 reads (26%) | called by muse, mutect2, varscan2
- SNX10 | c.-16G>T | 5'UTR (SNP) | VAF 107/421 reads (25%) | catalogued as rs190574019; called by mutect2, varscan2
- THSD4 | c.1906+58G>C | Intron (SNP) | VAF 30/60 reads (50%) | catalogued as COSV99967499; called by muse, mutect2, varscan2
- TRPC6 | c.1128+49G>T | Intron (SNP) | VAF 46/108 reads (43%) | catalogued as rs1186501156; called by mutect2, varscan2
- ZNF717 | c.*182G>T | 3'UTR (SNP) | VAF 109/186 reads (59%) | called by mutect2, varscan2
